Somatic mutation profile of tumor specimen TCGA-CH-5791-01A (aliquot TCGA-CH-5791-01A-11D-1576-08) from TCGA case TCGA-CH-5791, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.3 years (26,390 days).
Specimen TCGA-CH-5791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e88d135-423c-4136-b101-34320983819b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5791-10A (Blood Derived Normal), aliquot TCGA-CH-5791-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1f84e7-4ccd-49ad-887e-30795e932662

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Frame Shift Del 2, In Frame Del 2, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.210-1G>A p.X70_splice | Splice Site (SNP) | VAF 35/60 reads (58%) | hotspot (GDC flag); catalogued as rs1114167621, CS002683, COSV64288901, COSV64300623, COSV64300922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRD1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as rs141128784; called by muse, mutect2
- AFG3L2 | c.1928C>A p.T643K | Missense Mutation (SNP) | VAF 10/311 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52314266; called by muse, mutect2
- ANO4 | c.950G>A p.R317Q (on ENST00000392977 / NM_001286615.2; = p.R282Q on NM_178826.4) | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1202630749, COSV54594794; called by muse, mutect2, varscan2
- BCL6 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs960367912, COSV51651828; called by muse, mutect2, varscan2
- CCDC15 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 18/552 reads (3%) | catalogued as COSV61081574; called by muse, mutect2
- CEBPZ | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1401728175, COSV52206223, COSV99305392; called by muse, mutect2
- CRTAC1 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54001157; called by muse, mutect2, varscan2
- EML3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV53882326; called by muse, mutect2, varscan2
- FANCG | c.1059G>T p.R353S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1489928689, COSV62720466; called by muse, mutect2
- FRAS1 | c.4589C>T p.T1530M | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757251336, COSV53607772; called by muse, mutect2, varscan2
- GRXCR1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777472087, COSV67671604; called by muse, mutect2, varscan2
- LCE5A | c.300C>G p.S100R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.374); catalogued as COSV57500207, COSV57500399; called by muse, mutect2, varscan2
- LRP1B | c.6073C>A p.R2025S | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV67208397, COSV67214736; called by muse, mutect2, varscan2
- MAML2 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73263334; called by muse, mutect2, varscan2
- METTL3 | c.674T>G p.I225R | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52968305, COSV52968707; called by muse, mutect2, varscan2
- NAV2 | c.5368G>T p.A1790S (on ENST00000396087 / NM_001244963.2; = p.A1734S on NM_145117.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60659026; called by muse, mutect2, varscan2
- PLG | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs371746732, COSV51981567; called by muse, mutect2, varscan2
- PPEF1 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 100/157 reads (64%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV62995658; called by muse, mutect2, varscan2
- PPEF2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs550740753, COSV54422147; called by muse, mutect2, varscan2
- RAPH1 | c.3119T>C p.V1040A | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV55583649; called by muse, mutect2, varscan2
- SIDT2 | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV54056729; called by muse, mutect2
- SIGLEC1 | c.4063C>T p.R1355W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs149916347; called by muse, mutect2, varscan2
- SMC2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV53955215; called by muse, mutect2, varscan2
- TCN1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV57253107; called by muse, mutect2, varscan2
- TLX1 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64622464; called by muse, mutect2
- UBAC1 | c.624C>G p.N208K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.053); catalogued as COSV65614062; called by muse, mutect2, varscan2
- ZNF292 | c.5771G>A p.G1924D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs1191785376; called by muse, mutect2
- B3GNT4 | c.408_422delinsGCCGCACGTGCT p.I137_W141delinsPHVL | In Frame Del (DEL) | VAF 30/153 reads (20%) | called by pindel, varscan2*
- PCDHGB3 | c.1769_1778del p.K590Rfs*70 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- RSPO2 | c.184_186del p.F62del | In Frame Del (DEL) | VAF 43/143 reads (30%) | called by pindel, varscan2
- ZNF142 | c.4976_4981delinsTG p.Y1659Lfs*64 (on ENST00000411696 / NM_001379660.1; = p.Y1459Lfs*64 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/176 reads (22%) | called by pindel, varscan2*
- CXADR | c.324G>A p.T108= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as rs758306077, COSV53028733; called by muse, mutect2, varscan2
- DAO | c.618C>T p.D206= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs1467401052, COSV57322351; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENTPD7 | c.954C>T p.N318= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as rs768978614, COSV65112247; called by muse, mutect2
- GCN1 | c.811C>T p.L271= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV56106032; called by muse, mutect2, varscan2
- KCNQ3 | c.507C>T p.A169= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs1220196153, COSV101196420, COSV66469952; ClinVar: likely benign; called by muse, mutect2, varscan2
- PID1 | c.342A>T p.P114= (on ENST00000354069 / NM_001330156.1; = p.P112= on NM_017933.5) | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100819624, COSV62475269; called by muse, mutect2, varscan2
- ZNF641 | c.810G>T p.G270= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as COSV56390100; called by muse, mutect2
- ZZEF1 | c.2193G>A p.T731= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs995720241, COSV67557282; called by muse, mutect2, varscan2
- SSPOP | n.15436G>A | RNA (SNP) | VAF 9/15 reads (60%) | catalogued as rs780107728, COSV65129646; called by muse, mutect2, varscan2
